Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9ZK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9ZK-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Prostate gland, bilateral seminal vesicles, radical prostatectomy:
1. Prostatic adenocarcinoma, Gleason grade 5+4 = 9, with extensive extraprostatic extension and left seminal vesicle invasion, excised; see comment.
2. Right seminal vesicle, no tumor.
3. High-grade prostatic intraepithelial neoplasia, focal.
- B. Lymph nodes, right pelvic, dissection: No tumor in three lymph nodes (0/3).
- C. Lymph nodes, left pelvic, dissection: No tumor in three lymph nodes (0/3).

COMMENT:

The majority of the tumor is composed of solid sheets of tumor cells with large vacuoles that give the impression of gland formation however, these are signet-ring like cells and therefore this is consistent with Gleason pattern 5. Some areas are suspicious for lymphatic invasion.

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma, signet-ring cell like adenocarcinoma (Gleason pattern 5), hypernephromatoid carcinoma (Gleason pattern 4). *Per TSS, ~ 70% Signet ring.*
- **Location of tumor:**
- Left posterior mid gland, slides A12-A13.
- Right seminal vesicle junction, slide A21.
- Left seminal vesicle junction, slides A22-A23.
- **Estimated volume of tumor:** 1.9 cm³.
- **Gleason score:** 5 + 4.
- **Estimated volume > Gleason pattern 3:** 80-90%.
- **Involvement of capsule:** Tumor invades capsule (left posterior mid gland, slide A12; left posterior base, slides A22-A23).
- **Extraprostatic extension:** Present, extensive.
- **Margin status for tumor:** Negative (tumor is 1 mm from posterior margin in area of extraprostatic extension, slide A13).

*ICD-O-3
Adenocarcinoma, Signet ring cell
8490/3
Site: Prostate NOS C61.9
GJS 1/23/14*

[page 2 of 3]
- **Margin status for benign prostate glands:** No benign glands present at inked excision margin.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present, focal.
- **Tumor involvement of seminal vesicle:** Present, left side.
- **Perineural infiltration:** Present.
- **Lymph node status:** Negative; total number of nodes examined: Six.
- **AJCC/UICC stage:** pT3bN0.
-

Specimen(s) Received

A: Prostate and seminal vesicles
B: Lymph node, right pelvic
C: Lymph node, left pelvic

Clinical History

The patient is a [REDACTED]-year-old man with prostate cancer, Gleason grade 4+4 located in the left lateral base. [REDACTED]

Gross Description

The specimen is received in three parts, each labeled with the patient's name and medical record number. Part A is received fresh and Parts B and C are received in formalin.

Part A, additionally labeled "prostate and seminal vesicles," consists of a radical prostatectomy specimen (64 gm; 4.5 cm from apex to base x 6 cm in width x 4.5 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: There is one suspicious irregular, white-tan lesion (0.3 x 0.2 x 0.2 cm) in the left posterior quadrant of serial slice 4. This lesion abuts the closest inked margin. The anterior fibrous stroma is pink-red, roughened and appears closed. The remaining capsule is intact. The remaining prostatic parenchyma is pink-tan. The seminal vesicles/vas deferens bundles (right 3 x 1.5 x 0.5 cm; left 2.5 x 1.5 x 0.5 cm) are soft, lobulated, pink-tan. The left seminal vesicle has slight tan discoloration. Portions of the prostate is taken fresh by the

ORIENTED BY: Anatomic landmarks - seminal vesicles, urethra.

INKING:

- Right anterior: Green.
- Left anterior: Blue.
- Posterior: Black.

GROSS PHOTOGRAPHS: Yes.

TOTAL NUMBER OF SLICES (not including apex and base margin slices): 6.

AVERAGE SLICE THICKNESS: 0.5 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

A1-A2: Right apex.

A3-A4: Left apex.

Right anterior quadrant

A5: Slice 1.

A6: Slice 3.

A7: Slice 4.

Right posterior quadrant

A8: Slice 1.

A9: Slice 3.

A10: Slice 4.

Left posterior quadrant

A11: Slice 1.

A12: Slice 3.

A13: Slice 4 (suspicious lesion).

Left anterior quadrant

A14: Slice 1.

A15: Slice 3.

A16: Slice 4.

Bladder margins, entirely submitted in perpendicular sections

[page 3 of 3]
A17-A18: Right.
A19-A20: Left.
Prostatic/seminal vesicle junction and cross-section of vas deferens
A21: Right.
A22-A23: Left with discolored seminal vesicle.

Part B, labeled "right pelvic lymph nodes," consists of a single soft, irregular, pink-yellow, fatty tissue fragment measuring 4 x 3.3 x 1.3 cm. There are three candidate lymph nodes ranging from 1.2 x 0.8 x 0.2 cm to 2.2 x 1 x 0.5 cm. The specimen is entirely submitted as follows:

B1: One node, bisected.
B2: Two nodes, each bisected.
B3: Remaining fatty tissue.

Part C, labeled "#2 - left pelvic lymph nodes," consists of multiple soft, irregular, pink-yellow, fatty tissue fragments measuring 5 x 4.5 x 0.5 cm in aggregate. There are four candidate lymph nodes ranging from 0.7 x 0.5 x 0.3 cm to 2.3 x 1 x 0.4 cm. The specimen is entirely submitted as follows:

C1: One node, bisected.
C2: Two nodes, one bisected.
C3: One node, bisected.
C4-C5: Remaining fatty tissue.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out on

Source: NCI Genomic Data Commons file f26e8106-470d-41c2-b5a1-b5cf939c2e28 (TCGA-V1-A9ZK.9AD0F7C3-9DEB-427C-B8A3-007B874AB12A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).